Surgical pathology report (de-identified scan), TCGA case TCGA-10-0931, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0931-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

- (A) ABDOMINAL WALL NODULE:
HIGH GRADE CARCINOMA.
- (B) ANTERIOR ABDOMINAL PERITONEUM:
HIGH GRADE SEROUS CARCINOMA.
- (C) SMALL BOWEL NODULE:
HIGH GRADE SEROUS CARCINOMA.
- (D) MESENTERY SMALL INTESTINE:
HIGH GRADE SEROUS CARCINOMA.
- (E) RIGHT FALLOPIAN TUBE AND RIGHT OVARY:
OVARY, HIGH GRADE SEROUS CARCINOMA. THE TUMOR EXTENDS INTO THE PERITUBAL SOFT TISSUE.
- (F) LEFT FALLOPIAN TUBE AND LEFT OVARY:
OVARY, HIGH GRADE SEROUS CARCINOMA.
Fallopian tube, Walthard's rests, no tumor present.
- (G) CUL-DE-SAC TUMOR:
HIGH GRADE SEROUS CARCINOMA. WITH A SMALL AREA OF TRANSITIONAL CELL CARCINOMA.
- (H) CUL-DE-SAC TUMOR #2:
HIGH GRADE SEROUS CARCINOMA.
- (I) UTERUS AND CERVIX:
HIGH GRADE SEROUS CARCINOMA IN UTERINE SEROSA AND OUTER MYOMETRIUM.
Endometrial polyp.
Chronic endometritis.
Uterine leiomyomas.
Uterine cervix with squamous metaplasia, no tumor present.
- (J) OMENTUM:
HIGH GRADE SEROUS CARCINOMA IN ADIPOSE TISSUE.
- (K) CUL-DE-SAC TUMOR #3:
HIGH GRADE SEROUS CARCINOMA.
- (L) CUL-DE-SAC TUMOR #4:
HIGH GRADE SEROUS CARCINOMA.
- (M) CUL-DE-SAC CONTENTS:
HIGH GRADE SEROUS CARCINOMA.

GROSS DESCRIPTION

- (A) ABDOMINAL WALL NODULE – An irregular piece of adipose tissue 1.0 x 0.7 x 0.4 cm. There is a white, hard area at the center which is 3.0 x 3.0 x 2.0 cm. The specimen is bisected and entirely submitted for frozen section in A. [REDACTED]
*FS/DX: POORLY DIFFERENTIATED CARCINOMA, COULD BE MULLERIAN. [REDACTED]
- (B) ANTERIOR ABDOMINAL PERITONEUM – The specimen consists of a fragment of fibroadipose tissue (5.0 x 2.0 x 0.3 cm). The specimen is involved by tumor (4.2 cm). Representative sections are submitted in cassettes B1 and B2. [REDACTED]
- (C) SMALL BOWEL NODULE – Two tan-pink nodules (0.4 x 0.4 x 0.3 and 0.6 x 0.4 x 0.3 cm). Specimen is entirely submitted in C. [REDACTED]

[page 2 of 2]
(D) MESENTERY SMALL INTESTINE, tan-pink nodule (0.5 x 0.4 x 0.3 cm). Specimen is entirely submitted in [REDACTED]
(E) RIGHT TUBE AND OVARY - A friable papillary tumor mass (9.0 x 5.0 x 3.2 cm). The fallopian tube is 9.5 cm in length, 1.5 cm in average diameter. The cut surface of the fallopian tube contains tumor nodules (0.3 cm in diameter). Frozen section was performed. Sections are submitted as follows.

SECTION CODE: E1-E2, frozen section; E3-E11, samples of tumor; E12, sample of fallopian tube with tumor. [REDACTED]

*FS/DX: HIGH-GRADE CARCINOMA WITH PAPILLARY AREAS CONSISTENT WITH PRIMARY OF THE OVARY.

(F) LEFT TUBE, LEFT OVARY – The specimen consists of a portion of fallopian tube (7.0 cm in length, 0.8 cm in diameter), and a tumor-replaced distorted ovary (6.5 x 5.0 x 4.0 cm). The tumor involves the entire ovary and it shows extensive involvement of the surface. Sectioning of the tumor shows areas with different appearance. The majority of the tumor has a pink-red cut surface. Other areas show a white-yellow cut surface. The fallopian tube appears unremarkable.

SECTION CODE: F1-F10, ovary and tumor; F11, fallopian tube. [REDACTED]

(G) CUL-DE-SAC TUMOR – The specimen consists of an ovoid fragment of tan soft tissue (4.2 x 2.6 x 2.0 cm). The cut surface is tan-yellow. Representative sections are submitted in G1-G4. [REDACTED]

(H) CUL-DE-SAC TUMOR #2 – Three irregular hemorrhagic friable soft tissue fragments (2.7 x 2.5 x 1.2 cm in aggregate). Representative sections are submitted.

SECTION CODE: H, tumor. [REDACTED]

(I) UTERUS AND CERVIX – Uterus without adnexal structures (10.7 x 7.2 x 4.0 cm) with multiple friable tumor nodules predominantly on the posterior/inferior aspect. The remainder of the serosal surface is unremarkable. One sessile polyp is present on the anterior uterine wall (1.0 x 0.4 x 0.2 cm). The remainder of the endometrium is unremarkable and is 0.2 cm in greatest thickness. The myometrium is 2.4 cm thick and contains two leiomyomata measuring 0.3 and 1.5 cm in greatest diameter. The endocervical and cervical mucosa are unremarkable. Representative sections are submitted.

SECTION CODE: I1 and I2, polyp; I3, anterior endometrium; I4, anterior lower uterine segment; I5, posterior endometrium; I6, posterior lower uterine segment; I7 and I8, leiomyoma; I9, right cervix; I10, left cervix; I11-I17, tumor on the serosal aspect, I14, tumor around the lower uterine segment. [REDACTED]

(J) OMENTUM – An irregularly shaped segment of omentum (18.0 x 5.0 x 20.0 x 4.2 cm) with multiple tan-white firm tumor nodules ranging from 0.3 to 9.0 cm in greatest diameter. Representative sections are submitted.

SECTION CODE: J1-J7, tumor. [REDACTED]

(K) CUL-DE-SAC TUMOR #3- Multiple irregular tan hemorrhagic and fleshy tumor nodules (4.2 x 4.5 x 1.3 cm in aggregate). Representative sections are submitted.

SECTION CODE: K, tumor nodules. [REDACTED]

(L) CUL-DE-SAC TUMOR #4 – Multiple irregular hemorrhagic tumor fragments measuring 4.2 x 3.9 x 1.2 cm in aggregate. Representative sections are submitted. [REDACTED]

SECTION CODE: L1, tumor. [REDACTED]

(M) CUL-DE-SAC – Multiple fragmented pink-tan soft tissue (7.5 x 7.5 x 1.0 cm in aggregate). Representative sections are submitted in three cassettes.

SECTION CODE: M1-M3, representative sections. [REDACTED]

CLINICAL HISTORY

Ovarian cancer.

Start of ADDENDUM

Source: NCI Genomic Data Commons file e9abd4fc-26d7-4618-b7d1-c6cdb0bbe886 (TCGA-10-0931.45D8F828-6DFB-4E68-8282-F2EE74671461.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).